Somatic mutation profile of tumor specimen TCGA-DX-A48R-01A (aliquot TCGA-DX-A48R-01A-11D-A307-09) from TCGA case TCGA-DX-A48R, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 41.4 years (15,107 days).
Specimen TCGA-DX-A48R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50451885-a5d9-4e02-9da5-82f0bd143d2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A48R-10A (Blood Derived Normal), aliquot TCGA-DX-A48R-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87c4f5b8-342c-40f2-ae73-383387c25331

The open-access MAF lists 49 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 3, Intron 2, In Frame Del 2, Splice Site 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.5713G>T p.E1905* | Nonsense Mutation (SNP) | VAF 40/87 reads (46%) | catalogued as COSV101329994; called by muse, mutect2, varscan2
- ABCA13 | c.5714A>T p.E1905V | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV101329995; called by muse, mutect2, varscan2
- ACSS2 | c.14A>T p.E5V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV99489733; called by muse, mutect2, varscan2
- AP2A1 | c.2490C>A p.C830* | Nonsense Mutation (SNP) | VAF 45/84 reads (54%) | catalogued as COSV100571088, COSV58241058; called by muse, mutect2, varscan2
- ATP5MC3 | c.42C>A p.I14= | Splice Region (SNP) | VAF 26/133 reads (20%) | catalogued as COSV99507109, COSV99507118; called by muse, mutect2, varscan2
- CAVIN1 | c.981G>C p.K327N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100824529; called by muse, mutect2
- CDH8 | c.556G>T p.V186F | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100180616; called by muse, mutect2, varscan2
- CUBN | c.5992G>C p.D1998H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as COSV100912361; called by muse, mutect2, varscan2
- FCGBP | c.2629G>A p.G877S | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs549995848; called by muse, mutect2, varscan2
- HLTF | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV100026782; called by muse, mutect2, varscan2
- HUNK | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.968); catalogued as rs553993228, COSV99528291; called by muse, mutect2, varscan2
- JAG1 | c.2114G>C p.R705P | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV99652656; called by muse, mutect2, varscan2
- KCNH5 | c.1570-1G>T p.X524_splice | Splice Site (SNP) | VAF 49/91 reads (54%) | catalogued as COSV100525972; called by muse, mutect2, varscan2
- LENG8 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1029994784, COSV100457300; called by muse, mutect2, varscan2
- LRRC8B | c.2028C>A p.F676L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV100446486; called by muse, mutect2, varscan2
- MAGI2 | c.302-2A>T p.X101_splice | Splice Site (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100833898; called by muse, mutect2, varscan2
- MDN1 | c.12374G>A p.R4125Q | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs781648246, COSV101021041; called by muse, mutect2, varscan2
- MEIG1 | c.170A>G p.K57R | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV100988084; called by muse, mutect2, varscan2
- MUC16 | c.21407C>T p.T7136M | Missense Mutation (SNP) | VAF 123/245 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.647); catalogued as rs376066548; called by muse, mutect2, varscan2
- MYH2 | c.3428C>G p.S1143C | Missense Mutation (SNP) | VAF 406/1924 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV99819722; called by muse, varscan2
- OR1J2 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.012); catalogued as COSV100093168; called by muse, mutect2, varscan2
- OR2G3 | c.855A>T p.L285F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100180552; called by muse, mutect2
- OR8D1 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100766590; called by muse, mutect2, varscan2
- PAK3 | c.344G>A p.R115Q (on ENST00000262836 / NM_001324328.2; = p.R100Q on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT tolerated (0.22); PolyPhen benign (0.393); catalogued as rs1320774876, COSV53280616; called by muse, mutect2, varscan2
- PSTPIP2 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.523); catalogued as COSV101297343; called by muse, mutect2, varscan2
- ROM1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as COSV99605833; called by muse, varscan2
- ROM1 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV99605836; called by muse, varscan2
- ROM1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99605841; called by muse, varscan2
- RYR1 | c.3952G>A p.A1318T | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.253); catalogued as rs755824571, COSV100615284; called by muse, mutect2, varscan2
- SEC16B | c.2776G>A p.A926T | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs1311376621, COSV100381421, COSV100381954; called by muse, mutect2, varscan2
- SLC2A2 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100049202; called by muse, mutect2, varscan2
- TAS2R7 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs554036509, COSV53689469; called by muse, mutect2, varscan2
- TFAP2E | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1194094273, COSV100951458; called by muse, mutect2, varscan2
- ZC3H18 | c.1272_1283del p.D424_R427del | In Frame Del (DEL) | VAF 52/63 reads (83%) | catalogued as rs764951668; called by mutect2, varscan2
- ZMAT3 | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 106/166 reads (64%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.127); catalogued as COSV100265147; called by muse, mutect2, varscan2
- FDPS | c.1195_1203del p.A399_P401del | In Frame Del (DEL) | VAF 45/116 reads (39%) | called by mutect2, pindel, varscan2
- HNF4A | c.114del p.N38Kfs*88 | Frame Shift Del (DEL) | VAF 51/141 reads (36%) | called by mutect2, pindel, varscan2
- IGKV1-16 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 225/250 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- ANGPTL2 | c.591C>T p.I197= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as rs777044764, COSV99401324; called by muse, mutect2, varscan2
- ARFGEF1 | c.5247G>A p.E1749= | Silent (SNP) | VAF 46/75 reads (61%) | catalogued as COSV99141655; called by muse, mutect2, varscan2
- CC2D1A | c.435G>A p.A145= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs923710837, COSV100528373; called by muse, mutect2, varscan2
- MPDZ | c.516G>A p.E172= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs758015553, COSV59953702; called by muse, mutect2, varscan2
- NCOR1 | c.6717A>C p.P2239= | Silent (SNP) | VAF 42/511 reads (8%) | catalogued as COSV99248899; called by muse, mutect2
- NEB | c.12525C>T p.L4175= | Silent (SNP) | VAF 57/130 reads (44%) | catalogued as rs377183242; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKHD1 | c.873C>G p.T291= | Silent (SNP) | VAF 144/288 reads (50%) | catalogued as COSV100582314; called by muse, mutect2, varscan2
- TREML1 | c.231G>A p.T77= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as rs201231028; called by muse, mutect2, varscan2
- TTN | c.74316T>C p.D24772= (on ENST00000591111; = p.D17348= on NM_003319.4) | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV100603234; called by muse, mutect2, varscan2
- ADGRL2 | c.3626-700A>G | Intron (SNP) | VAF 146/301 reads (49%) | catalogued as COSV99588029; called by muse, mutect2, varscan2
- TTBK2 | c.823-7535C>T | Intron (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
